Surgical pathology report (de-identified scan), TCGA case TCGA-61-2087, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2087-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

- PART 1: OVARY, LEFT, RUPTURED TUMOR, EXCISION –
POORLY DIFFERENTIATED OVARIAN SEROUS ADENOCARCINOMA.
- PART 2: OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY –
A. POORLY DIFFERENTIATED OVARIAN SEROUS ADENOCARCINOMA.
B. CAPSULAR RUPTURE.
C. BENIGN FALLOPIAN TUBE.
- PART 3: INTER-PHRENIC MARGIN, LEFT DISTAL, EXCISION –
BENIGN FIBROFATTY AND FIBROMUSCULAR STROMA.
- PART 4: OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY –
A. BENIGN OVARY WITH MÜLLERIAN GLANDULAR INCLUSIONS.
B. BENIGN FALLOPIAN TUBE.
- PART 5: UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY –
A. CHRONIC CERVICITIS WITH REACTIVE SQUAMOUS METAPLASIA AND BENIGN ENDOCERVICAL GLANDULAR EPITHELIUM.
B. HYPERPLASTIC ENDOMETRIAL POLYP.
C. LEIOMYOMA.
- PART 6: LYMPH NODES, RIGHT PELVIC, LYMPH NODE DISSECTION –
NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3).
- PART 7: LYMPH NODE, RIGHT COMMON ILIAC, LYMPH NODE DISSECTION –
NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1).
- PART 8: LYMPH NODE, RIGHT PERIAORTIC, LYMPH NODE DISSECTION –
NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1).
- PART 9: LYMPH NODES, LEFT PELVIC, LYMPH NODE DISSECTION –
NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES (0/7).
- PART 10: LYMPH NODES, LEFT COMMON ILIAC, LYMPH NODE DISSECTION –
NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1).
- PART 11: LYMPH NODES, LEFT PERIAORTIC, LYMPH NODE DISSECTION –
NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2).
- PART 12: CUL-DE-SAC, POSTERIOR, TUMOR, EXCISION –
REACTIVE FIBROMUSCULAR STROMA WITH RECENT AND OLD HEMORRHAGE AND INFLAMMATION.
- PART 13: CUL-DE-SAC, ANTERIOR, BIOPSY –
REACTIVE FIBROVASCULAR STROMA WITH INFLAMMATION.
- PART 14: PERICOLIC GUTTER, LEFT, BIOPSY –
BENIGN SOFT TISSUE.
- PART 15: PERICOLIC GUTTER, RIGHT, BIOPSY –
BENIGN SOFT TISSUE.
- PART 16: OMENTUM, OMENTECTOMY –
BENIGN ADIPOSE TISSUE WITH CHRONIC INFLAMMATION AND REACTIVE MESOTHELIAL HYPERPLASIA.
- PART 17: DIAPHRAGM, BIOPSY –
BENIGN MUSCULAR TISSUE.

[page 2 of 2]
SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION: Left
PROCEDURE: TAH with salpingo-oophorectomy
TUMOR SIZE: Maximum dimension: 13 cm
TUMOR TYPE: Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE: Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN: Solid (3)
CYTOLOGIC ATYPIA: Marked (3)
MITOTIC COUNTS / 10hpf: 10-24 (2)
HISTOLOGIC GRADE (serous tumors): High grade
VASCULAR INVASION: No
TUMOR CAPSULE: Ruptured
SURFACE IMPLANTS: Not present
ASSOCIATED OTHER LESION: Surface epithelial inclusion
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING: Yes
LYMPH NODES EXAMINED: Total number of lymph nodes examined: 14
LYMPH NODES POSITIVE: Number of positive lymph nodes, Right: 0
Number of positive lymph nodes, Left: 0

T STAGE, PATHOLOGIC:

pT1c

T STAGE, PATHOLOGIC continued on next page**

T STAGE, PATHOLOGIC continued**

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IC

Source: NCI Genomic Data Commons file 4bd10b6d-c8b9-4da2-92d2-2a4acb802f8e (TCGA-61-2087.FADB191F-2726-4AFE-A146-1D912FF4B5B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).